Somatic mutation profile of tumor specimen 0DSBYD from CCDI case PBCHJU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,155 days).
Specimen 0DSBYD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d6dc736-74a9-4da0-9d54-67eee5cb60b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSCOT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fcc70ee-aa23-44ac-8300-7144e6869309

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1630_1637+1dup p.X544_splice (on ENST00000288602 / NM_001374244.1; = p.X504_splice on NM_004333.6 and 3 other RefSeq transcripts) | Splice Site (INS) | VAF 188/848 reads (22%) | called by mutect2, varscan2
- CPAMD8 | c.1918G>A p.A640T (on ENST00000651564; = p.A593T on NM_015692.5) | Missense Mutation (SNP) | VAF 38/886 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.041); called by muse, mutect2
- NPY5R | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 41/1489 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.272); called by muse, mutect2
- MT3 | c.-35C>T | 5'UTR (SNP) | VAF 12/402 reads (3%) | catalogued as COSV52366051; called by muse, mutect2
- RAB8A | c.324+36C>T | Intron (SNP) | VAF 95/308 reads (31%) | catalogued as rs770450111; called by mutect2, varscan2
- SERPINB13 | c.225+34A>T | Intron (SNP) | VAF 48/1204 reads (4%) | called by muse, mutect2
